Somatic mutation profile of tumor specimen TCGA-AZ-6599-01A (aliquot TCGA-AZ-6599-01A-11D-1771-10) from TCGA case TCGA-AZ-6599, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 72.4 years (26,438 days).
Specimen TCGA-AZ-6599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48c5f678-b1c3-44cb-9a1c-4c6e6f20b997.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6599-11A (Solid Tissue Normal), aliquot TCGA-AZ-6599-11A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1129ce53-9d09-4dbf-b606-2841c7cff7ff

The open-access MAF lists 271 somatic variants for this specimen: 190 protein-altering or splice-affecting, 71 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 71, Nonsense Mutation 15, Frame Shift Del 4, 5'UTR 4, 5'Flank 3, Splice Site 2, In Frame Del 2, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 26/32 reads (81%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DEGS1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1367958450, COSV60379003; ClinVar: likely pathogenic; called by muse, mutect2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 48/158 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 107/228 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAT1A | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs138556525, CM106326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.1600G>C p.V534L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.869); catalogued as COSV52743603; called by muse, mutect2, varscan2
- AC004922.1 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs200946215, COSV53163235; called by muse, mutect2, varscan2
- ADAM10 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99546843; called by muse, varscan2
- ADAMTS13 | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV63021104; called by muse, mutect2, varscan2
- ADAMTS2 | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142429109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.14303C>T p.S4768L | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs200130204, COSV67984486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHR | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs766592204, COSV54123303; called by muse, mutect2, varscan2
- AL031777.2 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1485084900, COSV61911877; called by muse, mutect2, varscan2
- ANKRD22 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64236460; called by muse, mutect2, varscan2
- ANO9 | c.2264G>A p.G755D | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV60383343; called by muse, mutect2, varscan2
- AQP2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761436417, COSV99550964; called by muse, mutect2, varscan2
- ATIC | c.1549_1561del p.E517Rfs*11 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as COSV52692904; called by mutect2, pindel, varscan2
- ATP10B | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59150484; called by muse, mutect2, varscan2
- ATP5MC2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100101094, COSV58601962; called by muse, varscan2
- BAP1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV56233960; called by muse, mutect2, varscan2
- BMP2K | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1188807457, COSV100622031; called by muse, mutect2, varscan2
- BRCA2 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66453135; called by muse, mutect2, varscan2
- C11orf53 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1325652405, COSV54721470; called by muse, mutect2, varscan2
- C15orf48 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 192/577 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100721132; called by muse, mutect2, varscan2
- C17orf100 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs1014014713, COSV56726197; called by muse, mutect2, varscan2
- C1orf116 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.914); catalogued as COSV100848039; called by muse, varscan2
- C6 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV54705990; called by muse, mutect2, varscan2
- CASP2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370097426, COSV100130967; called by muse, mutect2, varscan2
- CCDC88B | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760892212, COSV53702734; called by muse, mutect2, varscan2
- CCNYL1 | c.799G>A p.E267K (on ENST00000295414 / NM_001330218.2; = p.E197K on NM_152523.2) | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV99776109; called by muse, mutect2, varscan2
- CD19 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61188483; called by muse, mutect2, varscan2
- CDC42BPG | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.554); catalogued as COSV61347296; called by muse, mutect2, varscan2
- CFAP94 | c.278C>T p.S93F (on ENST00000320267 / NM_001352064.2; = p.S99F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57231968; called by muse, mutect2, varscan2
- CFDP1 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52209012; called by muse, mutect2, varscan2
- CLCA4 | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV55367848; called by muse, mutect2, varscan2
- COL14A1 | c.3955G>T p.V1319F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV52853589; called by muse, mutect2, varscan2
- COL6A2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as COSV100152809, COSV56004151; called by muse, mutect2, varscan2
- COPS6 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV57996210; called by muse, mutect2, varscan2
- CRB2 | c.3838C>T p.P1280S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284436486, COSV63502981; called by muse, mutect2, varscan2
- CREBBP | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.273); catalogued as COSV52122468; called by muse, mutect2, varscan2
- CREBZF | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs779903479, COSV52628888, COSV52630141; called by muse, varscan2
- DECR2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs749387015, COSV54794544; called by muse, mutect2, varscan2
- DLC1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 74/184 reads (40%) | catalogued as COSV52302174; called by muse, mutect2, varscan2
- DPYD | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs538703919, COSV100929024, COSV64594793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.17719C>T p.Q5907* (on ENST00000361203 / NM_001374722.1; = p.Q3604* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV55012088; called by muse, mutect2, varscan2
- DUOXA1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777729115, COSV50993464; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56127441; called by muse, mutect2, varscan2
- DYTN | c.851C>A p.T284K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV71751962; called by muse, mutect2, varscan2
- ECM2 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60740321; called by muse, mutect2, varscan2
- EGFR | c.2677C>T p.H893Y | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51797242; called by muse, varscan2
- ELN | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as rs1554683150, COSV52709879; called by muse, mutect2, varscan2
- EPHA6 | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV101065986; called by muse, mutect2, varscan2
- ERLIN1 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV64941092; called by muse, mutect2, varscan2
- ESRP1 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64409456; called by muse, mutect2, varscan2
- ETV4 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768121396, COSV52253177; called by muse, mutect2, varscan2
- FAM120C | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100070533; called by muse, mutect2, varscan2
- FAM71A | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54235514; called by muse, mutect2, varscan2
- FBP1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs121918190, CM970523, COSV64689288; called by muse, mutect2, varscan2
- FBXO46 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs762827807, COSV58348535; called by muse, mutect2, varscan2
- FFAR4 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65178840; called by muse, mutect2, varscan2
- FOXD4L5 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs745879707, COSV101073270, COSV101073300; called by muse, mutect2, varscan2
- FOXH1 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV56760936; called by muse, mutect2, varscan2
- FRAS1 | c.4481C>T p.S1494F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs778451404, COSV53607476; called by muse, mutect2, varscan2
- GABRB3 | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 130/373 reads (35%) | catalogued as COSV54650598, COSV54662524; called by muse, mutect2, varscan2
- GCLC | c.138+1G>A p.X46_splice (on ENST00000643939; = p.X50_splice on NM_001498.4) | Splice Site (SNP) | VAF 5/13 reads (38%) | catalogued as rs1244897935, COSV99988993; called by muse, mutect2, varscan2
- GHR | c.1874G>A p.C625Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100052251; called by muse, mutect2, varscan2
- GLTPD2 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 64/172 reads (37%) | catalogued as rs1183150814, COSV58702461, COSV58702830; called by muse, mutect2, varscan2
- GPRC5C | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV61236730; called by muse, varscan2
- GREB1 | c.4901C>T p.P1634L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV52188085; called by muse, mutect2
- GRIK3 | c.1170T>G p.F390L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV66139138; called by muse, mutect2
- GRP | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV56879463; called by muse, mutect2
- H2BC11 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.124); catalogued as COSV100345616, COSV60362089, COSV60362099; called by muse, mutect2, varscan2
- H2BC13 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV62440389; called by muse, mutect2, varscan2
- H3C1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as rs1238556326, COSV55119352, COSV99771933; called by muse, mutect2, varscan2
- H4C2 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs773766887, COSV55138676; called by muse, mutect2, varscan2
- HSD17B2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369773984; called by muse, mutect2, varscan2
- ICAM2 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99857056; called by muse, mutect2, varscan2
- INSR | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781369204, COSV57162003; called by muse, mutect2, varscan2
- KIAA1109 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1416885602, COSV99181974; called by muse, mutect2, varscan2
- KLF5 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750391044, COSV66614334; called by muse, mutect2, varscan2
- KLHDC9 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV100919707; called by muse, mutect2, varscan2
- L1TD1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.09); catalogued as rs146015306; called by muse, mutect2, varscan2
- LAMP2 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 73/97 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52352753; called by muse, mutect2, varscan2
- LGALS9C | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 135/642 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV60195586; called by muse, mutect2, varscan2
- LRIG2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV63161926; called by muse, mutect2, varscan2
- LTBP4 | c.662G>A p.S221N (on ENST00000308370 / NM_001042544.1; = p.S184N on NM_003573.2) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.351); catalogued as rs751596321, COSV52580870; called by muse, mutect2, varscan2
- LYPLA2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV65720611, COSV65720966; called by muse, mutect2, varscan2
- MAGEC3 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53579664, COSV53580203; called by muse, mutect2, varscan2
- MAP3K7 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV100997944, COSV65232942; called by muse, mutect2, varscan2
- MBD4 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV51444659; called by muse, mutect2
- MELTF | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV56380939; called by muse, mutect2, varscan2
- METTL7B | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1363716699, COSV57694837; called by muse, mutect2, varscan2
- MICAL2 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV56319910; called by muse, mutect2, varscan2
- MICAL3 | c.4300T>C p.S1434P | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV101490980; called by muse, mutect2, varscan2
- MIEN1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV54069791; called by muse, mutect2, varscan2
- MRAP2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs148904867, CM136934; called by muse, mutect2, varscan2
- MRNIP | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs373940235; called by muse, mutect2, varscan2
- MSRA | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV57801743; called by muse, mutect2, varscan2
- MXD4 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61466183; called by muse, mutect2, varscan2
- MYH14 | c.4579C>T p.R1527W | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs559910733, COSV51816658; called by muse, mutect2, varscan2
- MYPOP | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs536242462, COSV56193463; called by muse, mutect2, varscan2
- NCKAP5 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs371372513, COSV58450719; called by muse, mutect2
- NDOR1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1225894038, COSV61287585; called by muse, mutect2, varscan2
- NET1 | c.317C>T p.S106F (on ENST00000355029 / NM_001047160.3; = p.S52F on NM_005863.5) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV61791395; called by muse, mutect2, varscan2
- NEURL4 | c.3560C>T p.S1187F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1233000226, COSV59749322; called by muse, mutect2, varscan2
- NHLRC3 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 200/557 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100613106; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- OR11H4 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59560214; called by muse, mutect2, varscan2
- OR5AP2 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs564090082, COSV57257559; called by muse, mutect2, varscan2
- OR6B3 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs376861624; called by muse, mutect2, varscan2
- PCDH8 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1263350489, COSV58812442; called by muse, mutect2, varscan2
- PCF11 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV53530652; called by muse, mutect2, varscan2
- PCLO | c.7151C>T p.S2384F | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61632852; called by muse, mutect2, varscan2
- PDCD1LG2 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV67204504; called by muse, mutect2, varscan2
- PDILT | c.1602G>T p.Q534H | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV56701660; called by muse, varscan2
- PDPR | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55351544; called by muse, mutect2, varscan2
- PFKFB1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 41/50 reads (82%) | catalogued as rs372795411, COSV66628173; called by muse, mutect2, varscan2
- PHACTR4 | c.76G>A p.D26N (on ENST00000373839 / NM_001350159.2; = p.D36N on NM_023923.4) | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV65783851; called by muse, mutect2, varscan2
- PIGT | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99649277; called by muse, mutect2, varscan2
- PITPNM3 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs1383168508, COSV51470805; called by muse, varscan2
- PLCH2 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs558261253, COSV53942401; called by muse, mutect2, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by muse, mutect2, varscan2
- POR | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV67516815; called by muse, mutect2, varscan2
- PPP1R18 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV51295812; called by muse, mutect2, varscan2
- PRR14 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV54911676; called by muse, mutect2, varscan2
- PRUNE2 | c.9160G>A p.E3054K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99796405; called by muse, mutect2, varscan2
- RAB8A | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56291547; called by muse, mutect2, varscan2
- RBM10 | c.515del p.G172Afs*94 | Frame Shift Del (DEL) | VAF 46/70 reads (66%) | catalogued as COSV61311224; called by mutect2, pindel, varscan2
- RBM45 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV53720801; called by muse, mutect2, varscan2
- RBPJ | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs750670227, COSV100623812; called by muse, mutect2, varscan2
- RELL2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV51837199; called by muse, mutect2, varscan2
- REM2 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57465493; called by muse, mutect2, varscan2
- RHCG | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV51515787; called by muse, mutect2, varscan2
- RNASE1 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | catalogued as rs867624863, COSV61753967; called by muse, mutect2, varscan2
- RPRD2 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 45/142 reads (32%) | catalogued as COSV64816738; called by muse, mutect2, varscan2
- RRP15 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.685); catalogued as rs1558198740, COSV100860813, COSV65117835; called by muse, mutect2, varscan2
- SDHD | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); catalogued as rs1032016970, COSV54778152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDR39U1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV52160242; called by muse, mutect2, varscan2
- SDSL | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100615223, COSV61884628; called by muse, mutect2, varscan2
- SELE | c.1672G>T p.V558L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV60975195; called by muse, mutect2, varscan2
- SERPINB8 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54639517; called by muse, mutect2, varscan2
- SF3B2 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.935); catalogued as COSV59427862; called by muse, mutect2, varscan2
- SKA3 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs903271435, COSV53436189; called by muse, mutect2
- SLA | c.221G>A p.G74E (on ENST00000338087 / NM_001045556.3; = p.G114E on NM_006748.4) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.148); catalogued as COSV55074638; called by muse, varscan2
- SLC30A2 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV65332653; called by muse, mutect2, varscan2
- SLC7A11 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV54930053; called by muse, mutect2, varscan2
- SPG11 | c.5435G>A p.G1812E | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55994374; called by muse, mutect2, varscan2
- SPI1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57045413, COSV99909248; called by muse, mutect2, varscan2
- STK38 | c.813G>C p.W271C | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57708784; called by muse, mutect2, varscan2
- STRAP | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50308489; called by muse, mutect2, varscan2
- SUN1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61777362, COSV61778148; called by muse, mutect2, varscan2
- SYNE1 | c.20391G>A p.W6797* (on ENST00000367255 / NM_182961.4; = p.W6726* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 28/368 reads (8%) | catalogued as COSV99582832; called by muse, mutect2
- TBC1D9 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV71307392; called by muse, mutect2, varscan2
- TIAL1 | c.578T>C p.F193S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV64843166; called by muse, mutect2, varscan2
- TM4SF18 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99938082; called by muse, mutect2, varscan2
- TNC | c.3872A>G p.Q1291R | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs779335819, COSV60784457; called by muse, mutect2, varscan2
- TNIK | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV52681276; called by muse, mutect2, varscan2
- TNS2 | c.94C>T p.H32Y (on ENST00000314250 / NM_170754.4; = p.H42Y on NM_015319.2) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100048766, COSV58574485; called by muse, mutect2, varscan2
- TOM1 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as COSV101147158; called by muse, mutect2, varscan2
- TOMM40L | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100915931; called by muse, varscan2
- TRIM62 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs750420902, COSV52221235; called by muse, mutect2, varscan2
- TSHZ3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs776184849, COSV53664089, COSV53673939, COSV99553111; called by muse, mutect2
- TTLL13P | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV100296764; called by muse, mutect2, varscan2
- TTLL3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV59614262; called by muse, mutect2, varscan2
- TTLL4 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV51436233; called by muse, mutect2, varscan2
- TTLL5 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.842); catalogued as COSV100091949; called by muse, mutect2, varscan2
- TTN | c.82511T>A p.V27504D (on ENST00000591111; = p.V20080D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | PolyPhen probably damaging (0.925); catalogued as COSV100634007, COSV60386655; called by muse, mutect2, varscan2
- TUBB4A | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV99899976; called by muse, mutect2
- TUSC1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV63661754; called by muse, mutect2, varscan2
- UHRF2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs1429066554, COSV52792543; called by muse, mutect2, varscan2
- ULK1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58854282; called by muse, mutect2, varscan2
- UQCRC1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV52551609; called by muse, mutect2, varscan2
- USP6 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV100002970, COSV51481591; called by muse, mutect2, varscan2
- VPS13D | c.10552C>T p.R3518* | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | catalogued as rs752094174, COSV50636269; called by muse, mutect2, varscan2
- YTHDF3 | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV101572435, COSV72773039; called by muse, mutect2, varscan2
- YTHDF3 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101572436; called by muse, mutect2, varscan2
- ZFYVE9 | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1284558771, COSV55093462; called by muse, mutect2, varscan2
- ZMAT2 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as COSV51226974; called by muse, mutect2, varscan2
- ZNF169 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61764112; called by muse, mutect2
- ZNF169 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61764151, COSV61765666; called by muse, mutect2
- ZNF189 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52275101, COSV99407330; called by muse, mutect2, varscan2
- ZNF385D | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV55754230, COSV55770534; called by muse, mutect2, varscan2
- ZNF441 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100777392, COSV63539742; called by muse, mutect2, varscan2
- ZNF808 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV63119702; called by muse, mutect2, varscan2
- CDC42BPA | c.599+1del p.X200_splice | Splice Site (DEL) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- CKMT2 | c.974_976del p.L325del | In Frame Del (DEL) | VAF 60/171 reads (35%) | called by mutect2, pindel, varscan2
- F2R | c.390_395del p.M131_K132del | In Frame Del (DEL) | VAF 43/156 reads (28%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 44/417 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- PPP2R5B | c.1024del p.I342Ffs*11 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | called by mutect2*, pindel*, varscan2
- ABCA1 | c.5571C>T p.A1857= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs371988457; called by muse, mutect2, varscan2
- ADCK5 | c.720G>A p.G240= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV58233464; called by muse, mutect2, varscan2
- ANO1 | c.2439G>A p.P813= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs140131906; called by muse, mutect2, varscan2
- BRPF3 | c.2112C>T p.P704= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs200875879, COSV60207171; called by muse, mutect2, varscan2
- CAMSAP3 | c.1323G>A p.A441= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs945458603, COSV50333872; called by muse, mutect2, varscan2
- CCR9 | c.897C>T p.F299= (on ENST00000357632 / NM_031200.3; = p.F287= on NM_006641.4) | Silent (SNP) | VAF 64/201 reads (32%) | catalogued as COSV62940145; called by muse, mutect2, varscan2
- CGB5 | c.102C>T p.A34= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1453868584; called by muse, mutect2, varscan2
- CHRNE | c.876G>A p.Q292= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV53417808; called by muse, mutect2, varscan2
- COMMD9 | c.36C>T p.L12= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs759788895, COSV54672144; called by muse, mutect2, varscan2
- CYP2S1 | c.171C>T p.L57= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs897990238, COSV59505986; called by muse, mutect2, varscan2
- DDO | c.975G>A p.V325= (on ENST00000368924 / NM_001368172.1; = p.V266= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV64470059; called by muse, mutect2, varscan2
- DHRS4 | c.201G>A p.Q67= | Silent (SNP) | VAF 115/278 reads (41%) | catalogued as COSV100366076; called by muse, mutect2, varscan2
- DNTT | c.420G>A p.P140= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs201827729; called by muse, mutect2, varscan2
- DPM3 | c.6G>A p.T2= (on ENST00000341298; = p.T32= on NM_018973.3) | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as rs1247368193, COSV57596805; called by muse, mutect2, varscan2
- EXOC6B | c.64C>T p.L22= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs1288073390, COSV55553797; called by muse, mutect2, varscan2
- FAM83G | c.1509C>T p.P503= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as rs370625651; called by muse, mutect2, varscan2
- FBXO46 | c.708G>A p.A236= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs547331880, COSV58348529; called by muse, mutect2, varscan2
- FCGBP | c.9534C>T p.A3178= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as rs774328891; called by muse, mutect2, varscan2
- FCGR2C | c.267C>A p.L89= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV100912515, COSV100913216; called by muse, mutect2, varscan2
- GPRC5C | c.51G>A p.Q17= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV61236723; called by muse, varscan2
- GRM3 | c.837C>T p.D279= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100862885, COSV64467042; called by muse, mutect2, varscan2
- GSR | c.1026G>A p.L342= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs776555712, COSV55320541; called by muse, mutect2, varscan2
- HPSE2 | c.285C>T p.F95= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100986371; called by muse, mutect2, varscan2
- IFNB1 | c.411C>T p.L137= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV66525318, COSV66525764; called by muse, mutect2, varscan2
- IRX5 | c.1239G>A p.T413= | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as COSV58058729; called by muse, mutect2
- KLF5 | c.420C>T p.L140= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs781076393, COSV66614329; called by muse, mutect2, varscan2
- KLK10 | c.49C>T p.L17= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100011327; called by muse, mutect2, varscan2
- LBHD1 | c.18G>A p.G6= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV63472992; called by muse, varscan2
- LMTK3 | c.750C>T p.I250= | Silent (SNP) | VAF 58/174 reads (33%) | catalogued as COSV99541318; called by muse, mutect2, varscan2
- MAPK7 | c.150C>T p.D50= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV55190369; called by muse, mutect2, varscan2
- MUC5B | c.40C>T p.L14= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV71591898; called by muse, mutect2, varscan2
- MUC5B | c.9024C>T p.S3008= | Silent (SNP) | VAF 94/256 reads (37%) | catalogued as COSV71591901; called by muse, varscan2
- MYO5A | c.753C>T p.F251= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV62559792; called by muse, mutect2, varscan2
- MYOM3 | c.66C>T p.H22= | Silent (SNP) | VAF 103/369 reads (28%) | catalogued as COSV58393420; called by muse, mutect2, varscan2
- N4BP1 | c.2391C>T p.F797= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV52210670; called by muse, mutect2, varscan2
- NEU2 | c.66C>T p.I22= | Silent (SNP) | VAF 61/192 reads (32%) | catalogued as COSV52092638; called by muse, mutect2, varscan2
- NOA1 | c.24C>T p.F8= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV51736828; called by muse, mutect2, varscan2
- NPEPPS | c.153C>T p.F51= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as rs746589578, COSV100444038, COSV59102024; called by muse, mutect2, varscan2
- OR52N4 | c.441G>A p.G147= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs375479933; called by muse, mutect2, varscan2
- PCDHGA8 | c.1803C>T p.N601= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV53940091; called by muse, mutect2, varscan2
- PCLO | c.357C>T p.F119= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as COSV61632864; called by muse, mutect2, varscan2
- PCNX3 | c.5688G>A p.Q1896= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs1263676544, COSV63136595; called by muse, mutect2, varscan2
- PIK3C2B | c.2625G>A p.L875= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV65811166; called by muse, mutect2, varscan2
- PLD3 | c.339C>T p.L113= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100735297; called by muse, varscan2
- PLK3 | c.558C>T p.L186= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as COSV100221330; called by muse, mutect2, varscan2
- PPP1CA | c.879C>T p.F293= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV57236746; called by muse, mutect2, varscan2
- PPP1R16A | c.1140G>A p.P380= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs765057110, COSV52953010; called by muse, mutect2, varscan2
- PPP1R18 | c.1788C>T p.L596= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV51295832; called by muse, mutect2, varscan2
- RASSF3 | c.69C>T p.F23= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51685115; called by muse, mutect2, varscan2
- RMDN3 | c.78C>T p.F26= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV53023978; called by muse, mutect2, varscan2
- SELENOV | c.72G>A p.P24= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100112906; called by muse, mutect2, varscan2
- SEMA4B | c.528C>G p.V176= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV60172510, COSV60173395; called by muse, mutect2, varscan2
- SKAP1 | c.39C>T p.L13= | Silent (SNP) | VAF 59/160 reads (37%) | catalogued as rs887700343, COSV61146461; called by muse, mutect2, varscan2
- SPDYE1 | c.828C>T p.R276= | Silent (SNP) | VAF 22/383 reads (6%) | catalogued as COSV99324132; called by muse, mutect2
- STS | c.1392C>T p.F464= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV54268102; called by muse, varscan2
- SYBU | c.381G>A p.Q127= (on ENST00000276646 / NM_001099754.2; = p.Q126= on NM_017786.6) | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as COSV52617502; called by muse, mutect2, varscan2
- SYDE2 | c.708C>T p.V236= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV52315327; called by muse, mutect2, varscan2
- TGM2 | c.1653C>T p.Y551= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs761336603, COSV63931387; called by muse, mutect2, varscan2
- TIGD7 | c.918C>T p.S306= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV51915931; called by muse, mutect2, varscan2
- TMEM143 | c.1379G>A p.*460= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as rs1569020724, COSV53156368; called by muse, mutect2, varscan2
- TMEM45A | c.270C>T p.L90= | Silent (SNP) | VAF 86/267 reads (32%) | catalogued as COSV60253307; called by muse, mutect2, varscan2
- TP53I3 | c.867C>T p.F289= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV51980742; called by muse, varscan2
- TRPC4 | c.1203C>T p.I401= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs780024877, COSV58990513, COSV58999028; called by muse, mutect2, varscan2
- UBR4 | c.5778C>T p.L1926= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV64388829; called by muse, mutect2, varscan2
- USP33 | c.1821C>T p.N607= | Silent (SNP) | VAF 121/318 reads (38%) | catalogued as COSV62469252; called by muse, mutect2, varscan2
- VPS13D | c.8674C>T p.L2892= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV50636232; called by muse, mutect2, varscan2
- ZFYVE27 | c.240C>T p.L80= | Silent (SNP) | VAF 141/386 reads (37%) | catalogued as COSV61746624; called by muse, mutect2, varscan2
- ZNF169 | c.1356C>T p.H452= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV61764123; called by muse, mutect2
- ZNF169 | c.1440C>T p.H480= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV61764136; called by muse, mutect2
- ZNF785 | c.1098C>T p.S366= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs754271979, COSV67876311; called by muse, mutect2, varscan2
- ZRANB2 | c.18C>T p.F6= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV54671778; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918478 C>T | 5'Flank (SNP) | VAF 22/61 reads (36%) | catalogued as COSV62704628; called by muse, mutect2, varscan2
- ASIC4 | c.-161C>T | 5'UTR (SNP) | VAF 41/121 reads (34%) | catalogued as COSV100761956; called by muse, mutect2, varscan2
- CCDC28A | c.-159C>T | 5'UTR (SNP) | VAF 60/164 reads (37%) | catalogued as rs767210574, COSV60424922; called by muse, mutect2, varscan2
- DOCK8 | chr9:214817 G>A | 5'Flank (SNP) | VAF 16/33 reads (48%) | catalogued as COSV66688191; called by muse, mutect2, varscan2
- HAPLN2 | c.*2C>T | 3'UTR (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- MPV17L2 | c.-2C>T | 5'UTR (SNP) | VAF 17/32 reads (53%) | catalogued as rs758347194, COSV99718151; called by muse, varscan2
- OSBPL9 | c.319-15563G>A | Intron (SNP) | VAF 70/175 reads (40%) | catalogued as COSV61869469; called by muse, mutect2, varscan2
- SREK1 | chr5:66144499 C>T | 5'Flank (SNP) | VAF 24/60 reads (40%) | catalogued as rs975152116, COSV61904013; called by muse, mutect2, varscan2
- SSPOP | n.4148_4150del | RNA (DEL) | VAF 35/111 reads (32%) | catalogued as COSV50487309; called by mutect2, pindel, varscan2
- SWI5 | c.-59C>T | 5'UTR (SNP) | VAF 51/135 reads (38%) | catalogued as COSV60792010; called by muse, mutect2, varscan2
